Surgical pathology report (de-identified scan), TCGA case TCGA-FB-A5VM, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-A5VM-01A (Primary Tumor).

[page 1 of 2]
Gross Description: A. "Gallbladder." Length and greatest diameter: 9.5 x 2.1cm. Serosa: Smooth. Wall thickness: 0.2 cm. Mucosa: Slightly granular. Cystic duct: Dilated. Stones: None. Lymph nodes: One. B. "SMV lymph node." Received is a 0.8 cm firm lymph node. C. "Head o

Microscopic Description: Specimen resection type: Head/body/tail pancreas, duodenum, stomach, common bile duct, gallbladder. Procedure: Pancreaticoduodenectomy. Tumor location: Head. Tumor size (greatest dimension): 4.5 cm Histologic type: Ductal adenocarcinoma. Histologic grade: Poorly differentiated (<50%). Microscopic Tumor Extension: Carcinoma in situ, tumor confined to pancreas. Surgical margins: Distal pancreas margin: Free of neoplasm. Common bile duct margin: Free of neoplasm. Distal stomach/duodenum margin: Free of neoplasm. Retroperitoneal margins: Free of neoplasm. Angiolymphatic spread: No Perineural spread: Yes Treatment effect: No prior treatment. TNM-Staging: pT2 pN0 pMX LYMPH NODES: pN0 Peripancreatic, superior: 0 of 4 contain metastases Peripancreatic, inferior: 0 of 7 contain metastases Pancreaticoduodenal, anterior: 0 of 10 contain metastases Pancreaticoduodenal, posterior: 0 of 13 contain metastases Distant metastasis: pMX Other findings: Fibrosis, chronic pancreatitis, islet cell hyperplasia Other organs (if present): Gallbladder: Unremarkable Duodenum: Unremarkable Gastric antrum: Unremarkable LYMPH NODE (PERIMESENTERIC VEIN): 1 LYMPH NODE NEGATIVE FOR METASTASES. ROUND LIGAMENT: NEGATIVE FOR NEOPLASM.

Diagnosis Details: Pancreas: Adenocarcinoma without lymph node metastases

Comments: B. LYMPH NODE(SMV): NEGATIVE FOR CARCINOMA.

C. PANCREATIC DUCT MARGIN #1: ATYPICAL GLANDS, SUSPICIOUS FOR MALIGNANCY, DEFER TO PERMANENTS. D.

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 4.5 x 3.5 x 2 cm

Histologic type: Ductal adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Lymph nodes: 0/34 positive for metastasis (Peripancreatic superior, peripancreatic inferior, 0/34)

Lymphatic invasion: Absent

ICD-O-3

Adenocarcinoma, ductal 8500/3

Site Head of pancreas C25.0

9/18/13

[page 2 of 2]
Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: None

Comments: None

Source: NCI Genomic Data Commons file 57d0af43-a7fc-4dc3-bca9-7f5d04edc326 (TCGA-FB-A5VM.B3695BB7-243C-4A87-B8A3-70F45ECAFDDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).